Somatic mutation profile of tumor specimen ALCH-ABOQ-TTP1-A (aliquot ALCH-ABOQ-TTP1-A-1-0-D-A489-36) from ALCHEMIST case ALCH-ABOQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.1 years (21,569 days).
Specimen ALCH-ABOQ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 034699dd-6a27-4f42-b73e-22cf11ee1e21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABOQ-NB1-A (Blood Derived Normal), aliquot ALCH-ABOQ-NB1-A-1-0-D-A489-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3a317ceb-745b-4084-8e06-0247a8a65fa2

The open-access MAF lists 33 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 7, Intron 6, Frame Shift Ins 1, Nonsense Mutation 1, In Frame Del 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 127/596 reads (21%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 256/810 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCL9L | c.1064C>A p.T355N | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.334); catalogued as COSV52686910; called by muse, mutect2, varscan2
- CCDC197 | c.321C>A p.H107Q | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.69); catalogued as COSV100113649; called by muse, mutect2, varscan2
- CERKL | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs781492548; called by muse, mutect2, varscan2
- DNAH5 | c.6107G>A p.R2036H | Missense Mutation (SNP) | VAF 94/432 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760502991, COSV54263542; called by muse, mutect2, varscan2
- IFRD1 | c.142A>G p.I48V | Missense Mutation (SNP) | VAF 64/680 reads (9%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.489); catalogued as rs372855145; called by muse, mutect2
- LDHD | c.167G>A p.R56H | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1231640975; called by muse, mutect2
- PCDHA5 | c.285C>A p.C95* | Nonsense Mutation (SNP) | VAF 67/482 reads (14%) | catalogued as COSV65351388; called by muse, mutect2, varscan2
- TCOF1 | c.3416C>T p.A1139V (on ENST00000377797 / NM_001135243.1; = p.A1062V on NM_000356.4) | Missense Mutation (SNP) | VAF 101/590 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs1197900739; called by muse, mutect2, varscan2
- VSTM5 | c.35G>A p.R12Q | Missense Mutation (SNP) | VAF 47/182 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs533126575; called by muse, mutect2, varscan2
- ADGRL2 | c.2149T>G p.F717V (on ENST00000370717 / NM_001366005.1; = p.F704V on NM_012302.4) | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MYBL1 | c.2074A>G p.K692E | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- MYL10 | c.554C>T p.T185I | Missense Mutation (SNP) | VAF 22/283 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- OTX1 | c.497C>G p.S166W | Missense Mutation (SNP) | VAF 12/193 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2
- RAVER2 | c.652A>G p.M218V | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.952); called by muse, mutect2
- SERINC2 | c.405dup p.K136* (on ENST00000373709 / NM_178865.5; = p.K140* on NM_018565.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 36/377 reads (10%) | called by mutect2, pindel
- SGIP1 | c.1273T>A p.S425T | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- CYP2E1 | c.939G>T p.L313= | Silent (SNP) | VAF 12/139 reads (9%) | called by muse, mutect2
- FLG | c.9627G>A p.R3209= | Silent (SNP) | VAF 106/567 reads (19%) | catalogued as COSV64237338; called by muse, mutect2, varscan2
- GRIN2A | c.3054G>A p.V1018= | Silent (SNP) | VAF 65/247 reads (26%) | catalogued as rs868824530; called by muse, mutect2, varscan2
- IP6K3 | c.996G>C p.G332= | Silent (SNP) | VAF 68/429 reads (16%) | called by muse, mutect2, varscan2
- MUC12 | c.5454C>T p.S1818= (on ENST00000379442; = p.S1675= on NM_001164462.1) | Silent (SNP) | VAF 122/410 reads (30%) | catalogued as rs780753423; called by mutect2, varscan2
- NOL10 | c.1887G>C p.G629= | Silent (SNP) | VAF 13/260 reads (5%) | called by muse, mutect2
- NOS3 | c.474A>C p.A158= | Silent (SNP) | VAF 83/365 reads (23%) | called by muse, mutect2, varscan2
- AGBL3 | c.311-6853dup | Intron (INS) | VAF 4/32 reads (13%) | called by pindel, varscan2
- GLG1 | c.2053-194G>T | Intron (SNP) | VAF 25/203 reads (12%) | called by muse, mutect2, varscan2
- IMPA2 | c.490+3334T>G | Intron (SNP) | VAF 6/57 reads (11%) | called by muse, varscan2
- PLEKHH1 | c.3934-145C>T | Intron (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- SYNGR3 | chr16:1989769 C>T | 5'Flank (SNP) | VAF 162/714 reads (23%) | called by muse, mutect2, varscan2
- TTN | c.10360+2536C>T | Intron (SNP) | VAF 36/276 reads (13%) | catalogued as rs760239025, COSV100627731; called by muse, varscan2
- ZCCHC10 | c.107+3787A>C | Intron (SNP) | VAF 43/220 reads (20%) | called by muse, mutect2, varscan2
- ZNF90 | chr19:20121323 T>C | 3'Flank (SNP) | VAF 11/128 reads (9%) | catalogued as rs1555706533; called by muse, mutect2
